Surgical pathology report (de-identified scan), TCGA case TCGA-22-4607, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4607-01A (Primary Tumor).

[REDACTED] Surgical Pathology

TISSUE DESCRIPTION:

Right lower lobe lung (305 grams), superior (right upper and lower paratracheal) and inferior (subcarinal, inferior pulmonary ligament) mediastinal lymph nodes and N1 (right interlobar) lymph nodes

DIAGNOSIS:

Lung, right lower lobe, lobectomy: Grade 3 (of 4) squamous cell carcinoma forming a subpleural mass measuring 5 x 4.5 x 2.6 cm, extending into but not through the pleura. Bronchial margin is negative for tumor. Multiple (6) intrapulmonary peribronchial lymph nodes are negative for tumor.

Lymph nodes, superior and inferior mediastinal, N1, excision: Multiple superior (2 right lower and 2 right upper paratracheal) and inferior (6 subcarinal, 1 inferior pulmonary ligament) mediastinal lymph nodes and N1 (3 right interlobar) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file 824cd33a-1bb9-4547-bd06-eb7b981f0de7 (TCGA-22-4607.261AB183-8F0C-4288-9BDB-53FD2754DA31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).